TCGA case TCGA-BC-A10W — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/39baf24a-4032-4c23-b3fe-2c50df1881f6

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 50 years; Vital status: Dead; Days to death: 91 days.

Diagnoses (1)
1. Hepatocellular carcinoma, NOS: ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 50.8 years (18,562 days); Year of diagnosis: 2002; AJCC staging edition: 5th; AJCC pathologic T: T4; AJCC pathologic N: NX; AJCC pathologic M: MX; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant; Days to treatment start: 82 days; Days to treatment end: 85 days; Number of cycles: 1.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 91 days; Disease response: With Tumor.

Molecular and laboratory tests
- Prothrombin time (INR, as labelled on the TCGA clinical form) 0.9.
- Creatinine 0.8 mg/dL [Blood test normal range lower: 0.8; Blood test normal range upper: 1.4].
- Alpha Fetoprotein 79 ng/mL.
- Platelets 401 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 440].
- Albumin 2.8 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Total Bilirubin 1.4 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1.2].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 71 kg.
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis B Infection; Viral hepatitis serology tests: Hepatitis B Surface Antigen.

Family history
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BC-A10W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 460 mg.
  Slide TCGA-BC-A10W-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-BC-A10W-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BC-A10W-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BC-A10W-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 390 mg.
  Slide TCGA-BC-A10W-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 80; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Lobectomy.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis B Surface Antigen.
- Follow-up form: Tumor status: With tumor; New tumor event diagnosis indicator: No.
- Follow-up form, New tumor event: New tumor event type: No New Tumor Event.
- Drug treatment: Regimen number: 1.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 91 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 91 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 91 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BC-A10W-01A-11D-A12Y-01): tumor purity 0.73, ploidy 2.28, whole-genome doublings 0.
